Gene-level copy-number profile of tumor specimen MP2PRT-PATLPU-TMP1-A from MP2PRT case MP2PRT-PATLPU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,273 days).
Specimen MP2PRT-PATLPU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 44f68a2b-2f7f-48cd-af6f-479c3bd3fed9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PATLPU-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,729 have no estimate.
https://portal.gdc.cancer.gov/files/4d85e501-f8cf-4b62-9d0a-8c2870a1a0ad

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 99; copy number 1: 3,499; copy number 2: 51,644; copy number 3: 2,441; copy number 4: 1,211.

Homozygous deletions (total copy number 0; autosomes only): 99 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:87,379,880–87,459,044, 2 genes (within-gene range 0–2): AC068279.1, LINC01943.
- chr2:89,117,342–89,245,596, 15 genes (within-gene range 0–2): IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr2:89,959,979–89,990,221, 4 genes: IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25.
- chr2:242,047,695–242,175,634, 6 genes (within-gene range 0–2): LINC01880, AC093642.2, LINC01881, CICP10, SEPTIN14P2, RPL23AP88.
- chr6:157,289,025–157,323,601, 2 genes (within-gene range 0–2): TMEM242, LDHAL6FP.
- chr10:96,743,167–96,828,764, 3 genes: RNU6-1274P, RPL13AP5, MIR607.
- chr14:105,851,705–106,211,453, 65 genes (within-gene range 0–2) (broad region; genes not listed).
- chr17:40,597,113–40,648,654, 2 genes (within-gene range 0–2): AC004585.2, SMARCE1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,243. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
